Gene-level copy-number profile of specimen HCM-SANG-0269-C18-85A from HCMI case HCM-SANG-0269-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G2.
Specimen HCM-SANG-0269-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 82351e67-aaee-4d5a-8ad7-5964d0656b08.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0269-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/bdc6702d-4d7d-49af-a967-d1ecf02317e5

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2,593; copy number 2: 10,301; copy number 3: 23,718; copy number 4: 17,530; copy number 5: 1,145; copy number 6: 2,191; copy number 7: 1,203; copy number 8: 203; copy number 9: 10; copy number 10: 14; copy number 14: 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,432 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:46,734,827–46,993,581, 2 genes, copy number 7: COX7B2, GABRA4.
- chr6:42,050,513–44,553,281, 96 genes, copy number 8 (broad region; genes not listed).
- chr6:46,652,915–47,042,350, 10 genes, copy number 8–9: SLC25A27, AL591242.1, TDRD6, PLA2G7, ANKRD66, AL161618.1, MEP1A, ADGRF5, ADGRF5-AS1, ADGRF1.
- chr6:75,084,326–75,284,948, 3 genes, copy number 7–8: COL12A1, COX7A2, TMEM30A.
- chr8:40,104,169–40,353,133, 5 genes, copy number 7–14: AC087518.1, LINC02866, TCIM, AC022733.1, SIRLNT.
- chr8:41,509,593–41,578,421, 1 gene, copy number 8 (within-gene range 6–8): AC009630.1.
- chr8:41,540,381–42,555,195, 30 genes, copy number 7–8 (within-gene range 6–8): AC009630.2, AC009630.4, GPAT4, AC009630.3, NKX6-3, ANK1, MIR486-1, MIR486-2, AC113133.1, Y_RNA, AC027702.1, RN7SL149P, KAT6A, AC090571.1, AC103724.1, AC103724.2, AC103724.4, AC103724.3, AP3M2, PLAT, AC083973.1, IKBKB, POLB, RPL5P23, DKK4, VDAC3, SLC20A2, AC093367.1, AC090739.1, SMIM19.
- chr8:81,439,436–81,842,866, 19 genes, copy number 7–8: AC018616.1, PMP2, FABP9, FABP4, AC023644.1, FTH1P11, FABP12, IMPA1P1, NIPA2P4, RPS26P34, SLC10A5P1, IMPA1, SLC10A5, AC132219.2, ZFAND1, CHMP4C, AC132219.1, SNX16, HNRNPA1P36.
- chr8:94,127,162–94,707,466, 15 genes, copy number 7–8 (within-gene range 6–8): CDH17, AP003478.1, GEM, RPS4XP10, RAD54B, FSBP, VIRMA, AC023632.5, AC023632.2, AC023632.1, AC023632.3, AC023632.4, AC108860.2, ESRP1, Metazoa_SRP.
- chr8:106,980,967–106,981,571, 1 gene, copy number 7: AP003789.1.
- chr8:119,419,910–119,480,775, 2 genes, copy number 7 (within-gene range 4–7): AC021733.2, AC021733.3.
- chr8:123,768,439–123,815,452, 1 gene, copy number 7: FAM91A1.
- chr8:125,091,679–125,541,373, 5 genes, copy number 7 (within-gene range 5–7): NSMCE2, RN7SL329P, AC084083.1, TRIB1, AC091114.1.
- chr8:139,508,701–139,704,109, 2 genes, copy number 7: AC090093.1, KCNK9.
- chr8:142,611,049–142,682,725, 5 genes, copy number 7: ARC, AP006547.1, AC108002.2, JRK, PSCA.
- chr9:60,914,407–61,627,683, 14 genes, copy number 7–9: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3, SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D.
- chr9:61,665,579–61,666,386, 1 gene, copy number 9: AL935212.2.
- chr9:63,703,065–63,720,441, 2 genes, copy number 7: AL591438.2, CDRT15P7.
- chr14:18,395,626–18,419,273, 2 genes, copy number 7: CR383658.2, BNIP3P6.
- chr20:3,659,248–16,573,448, 184 genes, copy number 7–10 (within-gene range 6–10) (broad region; genes not listed).
- chr20:19,756,390–64,327,972, 1,032 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,082. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
